Somatic mutation profile of tumor specimen ALCH-B3JS-TTP1-A (aliquot ALCH-B3JS-TTP1-A-1-0-D-A80D-36) from ALCHEMIST case ALCH-B3JS, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 66.4 years (24,264 days).
Specimen ALCH-B3JS-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4865456c-cfa7-48ce-9796-7e4d5c2d00e3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B3JS-NB1-A (Blood Derived Normal), aliquot ALCH-B3JS-NB1-A-1-0-D-A80D-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/01ad898b-a852-4a04-961b-c587352901ad

The open-access MAF lists 400 somatic variants for this specimen: 279 protein-altering or splice-affecting, 71 silent, 50 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 253, Silent 71, Intron 19, Nonsense Mutation 13, RNA 12, 3'UTR 11, Splice Site 5, Frame Shift Del 4, 5'UTR 4, Splice Region 3, 5'Flank 3, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 88/392 reads (22%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCB11 | c.646C>A p.Q216K | Missense Mutation (SNP) | VAF 32/349 reads (9%) | SIFT tolerated (1); PolyPhen possibly damaging (0.487); catalogued as rs1350485320, COSV55603324; called by muse, mutect2
- ACOX1 | c.787G>A p.G263S | Missense Mutation (SNP) | VAF 38/383 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs751710138; called by muse, mutect2
- ACSM5 | c.329G>A p.C110Y | Missense Mutation (SNP) | VAF 18/260 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs1233946584; called by muse, mutect2
- ADAMTS5 | c.2296A>G p.K766E | Missense Mutation (SNP) | VAF 14/146 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs184462984; called by muse, mutect2
- ADGRL3 | c.1306G>T p.D436Y (on ENST00000506720 / NM_001322402.2; = p.D368Y on NM_015236.6) | Missense Mutation (SNP) | VAF 20/218 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV72272307; called by muse, mutect2
- ANKRD30BL | c.88G>T p.D30Y | Missense Mutation (SNP) | VAF 26/289 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.044); catalogued as COSV99724555; called by muse, mutect2
- AREL1 | c.125G>A p.G42E | Missense Mutation (SNP) | VAF 22/578 reads (4%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.273); catalogued as rs1310696797; called by muse, mutect2
- ARHGAP28 | c.757G>T p.V253F (on ENST00000383472 / NM_001366230.1; = p.V94F on NM_001010000.3) | Missense Mutation (SNP) | VAF 13/162 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.178); catalogued as COSV51637064; called by muse, mutect2
- ASTN2 | c.1267C>A p.R423S (on ENST00000313400 / NM_001365069.1; = p.R372S on NM_014010.5) | Missense Mutation (SNP) | VAF 18/179 reads (10%) | SIFT tolerated, low confidence (0.63); PolyPhen probably damaging (0.931); catalogued as COSV57753974; called by muse, mutect2, varscan2
- ATM | c.8083G>A p.G2695S | Missense Mutation (SNP) | VAF 47/390 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1555127166, COSV53741150, COSV53763120; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP11C | c.2447C>G p.S816W | Missense Mutation (SNP) | VAF 40/319 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59562505, COSV59576393; called by muse, mutect2, varscan2
- BRCA2 | c.6851C>G p.S2284* | Nonsense Mutation (SNP) | VAF 6/102 reads (6%) | catalogued as COSV66450211; called by muse, mutect2
- C4orf54 | c.152C>T p.S51L | Missense Mutation (SNP) | VAF 24/236 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as rs1004736458; called by muse, mutect2, varscan2
- CAND2 | c.483G>T p.M161I | Missense Mutation (SNP) | VAF 35/208 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs1006598325; called by muse, mutect2, varscan2
- CAVIN2 | c.1138G>A p.E380K | Missense Mutation (SNP) | VAF 26/312 reads (8%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.124); catalogued as COSV58426201; called by muse, mutect2
- CELF5 | c.1278C>G p.I426M | Missense Mutation (SNP) | VAF 12/209 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.905); catalogued as COSV99485871; called by muse, mutect2
- CHRM4 | c.1212del p.I405Ffs*3 | Frame Shift Del (DEL) | VAF 18/87 reads (21%) | catalogued as COSV58996011; called by mutect2, pindel, varscan2
- CPXM2 | c.1537G>T p.G513C | Missense Mutation (SNP) | VAF 34/364 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1468690860; called by muse, mutect2
- CT47A6 | c.742G>T p.E248* | Nonsense Mutation (SNP) | VAF 24/113 reads (21%) | catalogued as COSV101342115; called by muse, mutect2, varscan2
- CTAG2 | c.40G>A p.D14N | Missense Mutation (SNP) | VAF 26/288 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.19); catalogued as rs1252217340; called by muse, mutect2
- CTNNA2 | c.2295G>T p.Q765H | Missense Mutation (SNP) | VAF 25/210 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.012); catalogued as COSV100559900; called by muse, mutect2, varscan2
- CYP4F22 | c.1484G>A p.R495H | Missense Mutation (SNP) | VAF 23/245 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.231); catalogued as rs1306854762; called by muse, mutect2
- DLG1 | c.2599C>G p.H867D (on ENST00000419354 / NM_001290983.1; = p.H889D on NM_004087.2) | Missense Mutation (SNP) | VAF 23/356 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.664); catalogued as rs1389756156; called by muse, mutect2
- DMD | c.5084T>C p.I1695T | Missense Mutation (SNP) | VAF 31/275 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.433); catalogued as COSV100818673; called by muse, mutect2, varscan2
- DVL3 | c.980G>T p.G327V | Missense Mutation (SNP) | VAF 39/260 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57455599; called by muse, mutect2, varscan2
- ENTPD5 | c.517G>T p.G173C | Missense Mutation (SNP) | VAF 25/244 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769740539; called by muse, mutect2, varscan2
- EVX2 | c.574C>A p.R192S | Missense Mutation (SNP) | VAF 13/248 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV57962291; called by muse, mutect2
- FLG | c.8318G>A p.S2773N | Missense Mutation (SNP) | VAF 50/973 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.103); catalogued as rs755462597; called by muse, mutect2
- GFAP | c.841G>C p.E281Q | Missense Mutation (SNP) | VAF 13/206 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV53650853; called by muse, mutect2
- GPR101 | c.982G>T p.E328* | Nonsense Mutation (SNP) | VAF 29/144 reads (20%) | catalogued as COSV53239064; called by muse, mutect2, varscan2
- HDGFL2 | c.1810G>A p.G604S | Missense Mutation (SNP) | VAF 18/193 reads (9%) | SIFT deleterious (0); catalogued as rs1309675662; called by muse, mutect2, varscan2
- HSPH1 | c.1265G>T p.R422L | Missense Mutation (SNP) | VAF 21/309 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.426); catalogued as COSV60710345; called by muse, mutect2
- IL1RAPL1 | c.1435C>A p.P479T | Missense Mutation (SNP) | VAF 41/332 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV56274784; called by muse, mutect2, varscan2
- IL2RG | c.59G>A p.G20E | Missense Mutation (SNP) | VAF 12/176 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.762); catalogued as COSV52147307; called by muse, mutect2
- IMP3 | c.197C>G p.P66R | Missense Mutation (SNP) | VAF 12/158 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs1373435873; called by muse, mutect2
- ITGB4 | c.3929G>C p.R1310P | Missense Mutation (SNP) | VAF 12/101 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52322892; called by muse, mutect2, varscan2
- ITIH6 | c.1243C>T p.R415C | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.415); catalogued as COSV99513032; called by muse, mutect2
- KCNK15 | c.857C>T p.S286F | Missense Mutation (SNP) | VAF 22/141 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.266); catalogued as rs1487626193; called by muse, mutect2, varscan2
- KMT2D | c.15926C>A p.P5309H | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56442326; called by muse, mutect2, varscan2
- LGR6 | c.1744G>T p.V582L (on ENST00000367278 / NM_001017403.1; = p.V530L on NM_021636.3) | Missense Mutation (SNP) | VAF 21/295 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.152); catalogued as COSV99706530; called by muse, mutect2
- LRBA | c.5230A>G p.I1744V | Missense Mutation (SNP) | VAF 36/461 reads (8%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs1321133451; called by muse, mutect2
- LRRN3 | c.962G>T p.R321I | Missense Mutation (SNP) | VAF 25/235 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV57818688; called by muse, mutect2
- LRRTM4 | c.717C>A p.N239K | Missense Mutation (SNP) | VAF 12/238 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101297559; called by muse, mutect2
- MANEA | c.1060C>T p.P354S | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV104415343, COSV62589323; called by muse, mutect2
- MED13L | c.2554G>T p.V852F | Missense Mutation (SNP) | VAF 14/394 reads (4%) | SIFT tolerated (0.65); PolyPhen benign (0.305); catalogued as COSV99929421; called by muse, mutect2
- MPP1 | c.96del p.P33Qfs*8 | Frame Shift Del (DEL) | VAF 35/174 reads (20%) | catalogued as COSV65728197; called by mutect2, pindel, varscan2
- MUC17 | c.8G>T p.R3M | Missense Mutation (SNP) | VAF 18/129 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.831); catalogued as COSV100075836; called by muse, mutect2, varscan2
- MUC17 | c.9674C>G p.T3225S | Missense Mutation (SNP) | VAF 15/168 reads (9%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.899); catalogued as COSV60279020; called by muse, mutect2
- NCR1 | c.449C>A p.T150K | Missense Mutation (SNP) | VAF 27/247 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52556858; called by muse, mutect2, varscan2
- NSD1 | c.4539G>T p.E1513D | Missense Mutation (SNP) | VAF 54/491 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs147540632; called by muse, mutect2, varscan2
- NYX | c.97G>T p.A33S | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT tolerated (0.53); PolyPhen benign (0.005); catalogued as rs1224665975; called by muse, mutect2, varscan2
- OR2G3 | c.272C>T p.T91M | Missense Mutation (SNP) | VAF 35/264 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.561); catalogued as rs147947949; called by muse, mutect2, varscan2
- OR2L13 | c.324T>A p.C108* | Nonsense Mutation (SNP) | VAF 51/477 reads (11%) | catalogued as COSV100813865; called by muse, mutect2, varscan2
- OR5B3 | c.254T>C p.I85T | Missense Mutation (SNP) | VAF 5/95 reads (5%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs940808897; called by muse, mutect2
- OR5I1 | c.320G>T p.C107F | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.991); catalogued as rs774540167, COSV100041305; called by muse, mutect2, varscan2
- OTOF | c.490G>T p.G164* | Nonsense Mutation (SNP) | VAF 8/72 reads (11%) | catalogued as rs1337721316; called by muse, mutect2, varscan2
- PCDH10 | c.2866C>A p.P956T | Missense Mutation (SNP) | VAF 16/256 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs763670241; called by muse, mutect2
- PCDHB3 | c.1847del p.G616Afs*15 | Frame Shift Del (DEL) | VAF 47/459 reads (10%) | catalogued as COSV50606885, COSV99166133; called by mutect2, pindel, varscan2
- PEAR1 | c.1049G>T p.C350F | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1397636191; called by muse, mutect2, varscan2
- PMS1 | c.1406A>G p.N469S | Missense Mutation (SNP) | VAF 42/494 reads (9%) | SIFT tolerated (0.42); PolyPhen benign (0.031); catalogued as COSV59715015; called by muse, mutect2
- PTPRB | c.110C>G p.S37C | Missense Mutation (SNP) | VAF 35/201 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.859); catalogued as COSV99718321; called by muse, mutect2, varscan2
- PTPRVP | n.4457G>T | Splice Region (SNP) | VAF 14/122 reads (11%) | catalogued as rs1179916211; called by muse, mutect2
- RP1L1 | c.6862C>A p.P2288T | Missense Mutation (SNP) | VAF 17/131 reads (13%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.703); catalogued as rs758504223; called by muse, mutect2, varscan2
- RXFP3 | c.931G>A p.G311R | Missense Mutation (SNP) | VAF 13/118 reads (11%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.617); catalogued as rs753746474; called by muse, mutect2, varscan2
- SARM1 | c.680C>T p.A227V | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1555585220, COSV50229547; called by muse, mutect2, varscan2
- SCAMP1 | c.829A>G p.I277V | Missense Mutation (SNP) | VAF 20/191 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.215); catalogued as rs762952835; called by muse, mutect2
- SIPA1L2 | c.1421G>T p.R474L | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.2); catalogued as COSV104394475; called by muse, mutect2, varscan2
- SLC8A3 | c.417G>A p.M139I | Missense Mutation (SNP) | VAF 16/306 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.241); catalogued as COSV63523256; called by muse, mutect2
- SOX6 | c.310G>A p.E104K | Missense Mutation (SNP) | VAF 28/568 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.2); catalogued as rs545452739, COSV57048270; called by muse, mutect2
- SPATA31D1 | c.1464C>G p.H488Q | Missense Mutation (SNP) | VAF 36/490 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.15); catalogued as rs369941995; called by muse, mutect2
- SPATA48 | c.805G>T p.A269S | Missense Mutation (SNP) | VAF 22/251 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.031); catalogued as COSV51674672; called by muse, mutect2
- SYNGR1 | c.526G>C p.A176P | Missense Mutation (SNP) | VAF 36/334 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.831); catalogued as rs757785928, COSV59560908; called by muse, mutect2
- TBCD | c.304G>T p.A102S | Missense Mutation (SNP) | VAF 10/196 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.343); catalogued as COSV99052676; called by muse, mutect2
- TCERG1L | c.1450C>T p.R484C | Missense Mutation (SNP) | VAF 13/180 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64047638; called by muse, mutect2
- TENM1 | c.6422G>T p.G2141V | Missense Mutation (SNP) | VAF 8/93 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV64431423; called by muse, mutect2
- TM6SF2 | c.979C>T p.R327C | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs756458112; called by muse, mutect2, varscan2
- TRPA1 | c.2670C>G p.I890M | Missense Mutation (SNP) | VAF 27/261 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.355); catalogued as COSV51564838; called by muse, mutect2, varscan2
- TUFT1 | c.217G>A p.G73R | Missense Mutation (SNP) | VAF 58/360 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV61948548; called by muse, varscan2
- ULK4 | c.3566G>T p.G1189V | Missense Mutation (SNP) | VAF 39/281 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV100096257; called by muse, mutect2, varscan2
- USH2A | c.3796C>A p.P1266T | Missense Mutation (SNP) | VAF 16/302 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56410738; called by muse, mutect2
- ABCA8 | c.1928A>G p.D643G | Missense Mutation (SNP) | VAF 16/122 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.452); called by muse, mutect2, varscan2
- AC013489.1 | c.97G>C p.G33R | Missense Mutation (SNP) | VAF 29/230 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- ADCY8 | c.1919C>G p.A640G | Missense Mutation (SNP) | VAF 40/356 reads (11%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.846); called by muse, mutect2
- AGA | c.698G>T p.G233V | Missense Mutation (SNP) | VAF 34/448 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ALG11 | c.1194G>T p.E398D | Missense Mutation (SNP) | VAF 20/346 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- AMPD1 | c.1558T>G p.F520V | Missense Mutation (SNP) | VAF 46/398 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANK2 | c.5402C>A p.T1801N | Missense Mutation (SNP) | VAF 19/163 reads (12%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- ANK2 | c.11355G>T p.Q3785H | Missense Mutation (SNP) | VAF 27/319 reads (8%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.413); called by muse, mutect2
- ASXL3 | c.6709C>G p.P2237A | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AUP1 | c.1112C>T p.T371I | Missense Mutation (SNP) | VAF 31/309 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- BANK1 | c.887G>T p.G296V | Missense Mutation (SNP) | VAF 15/134 reads (11%) | SIFT tolerated (0.55); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- BCL11B | c.2471A>G p.Y824C (on ENST00000357195 / NM_001282237.2; = p.Y753C on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/323 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- BDH2 | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 13/145 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- BRWD3 | c.5213C>G p.S1738* | Nonsense Mutation (SNP) | VAF 55/541 reads (10%) | called by muse, mutect2, varscan2
- BTG1 | c.443G>T p.S148I | Missense Mutation (SNP) | VAF 41/348 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.695); called by muse, mutect2, varscan2
- C16orf91 | c.127G>C p.E43Q | Missense Mutation (SNP) | VAF 14/214 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.93); called by muse, mutect2
- C5orf34 | c.1538A>T p.Q513L | Missense Mutation (SNP) | VAF 15/147 reads (10%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.735); called by muse, mutect2, varscan2
- CAAP1 | c.890A>T p.D297V | Missense Mutation (SNP) | VAF 22/250 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CACNA1B | c.2036T>A p.V679D | Missense Mutation (SNP) | VAF 10/178 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2
- CARD11 | c.1601C>G p.A534G | Missense Mutation (SNP) | VAF 19/166 reads (11%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCNB3 | c.491C>G p.P164R | Missense Mutation (SNP) | VAF 36/257 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.307); called by muse, mutect2, varscan2
- CDC34 | c.544A>T p.K182* | Nonsense Mutation (SNP) | VAF 16/141 reads (11%) | called by muse, mutect2, varscan2
- CFAP65 | c.2990A>G p.K997R | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.242); called by muse, mutect2, varscan2
- CHD5 | c.1343C>A p.P448H | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- CIB4 | c.226C>A p.H76N | Missense Mutation (SNP) | VAF 15/208 reads (7%) | SIFT tolerated (0.56); PolyPhen benign (0.015); called by muse, mutect2
- CMSS1 | c.233T>C p.I78T | Missense Mutation (SNP) | VAF 19/144 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CMTR2 | c.1432C>T p.Q478* | Nonsense Mutation (SNP) | VAF 25/149 reads (17%) | called by muse, mutect2, varscan2
- CNTNAP3 | c.2017G>T p.A673S | Missense Mutation (SNP) | VAF 19/231 reads (8%) | SIFT tolerated (0.68); PolyPhen benign (0.07); called by muse, mutect2
- COL12A1 | c.1993A>T p.T665S | Missense Mutation (SNP) | VAF 29/529 reads (5%) | SIFT tolerated (0.71); PolyPhen benign (0.083); called by muse, mutect2
- COL19A1 | c.1951T>G p.L651V | Missense Mutation (SNP) | VAF 31/330 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.357); called by muse, mutect2
- COL1A2 | c.922G>T p.A308S | Missense Mutation (SNP) | VAF 86/854 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.003); called by muse, mutect2
- COL26A1 | c.1276G>A p.G426R (on ENST00000313669 / NM_001278563.3; = p.G424R on NM_133457.4) | Missense Mutation (SNP) | VAF 23/179 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.658); called by muse, mutect2, varscan2
- COPG2 | c.2540A>T p.D847V | Missense Mutation (SNP) | VAF 22/303 reads (7%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.606); called by muse, mutect2
- CPNE4 | c.1217A>T p.Q406L | Missense Mutation (SNP) | VAF 35/230 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- CRB1 | c.3767C>T p.S1256L | Missense Mutation (SNP) | VAF 14/400 reads (4%) | SIFT tolerated (0.61); PolyPhen benign (0.072); called by muse, mutect2
- CREB3L1 | c.1478G>A p.G493D | Missense Mutation (SNP) | VAF 8/150 reads (5%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0); called by muse, mutect2
- CSMD3 | c.1994G>C p.G665A (on ENST00000297405 / NM_001363185.1; = p.G561A on NM_052900.3) | Missense Mutation (SNP) | VAF 22/324 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); called by muse, mutect2
- CSMD3 | c.238G>C p.G80R | Missense Mutation (SNP) | VAF 44/314 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CT47A6 | c.742+1G>T p.X248_splice | Splice Site (SNP) | VAF 24/111 reads (22%) | called by muse, mutect2, varscan2
- CTAG2 | c.444G>C p.M148I | Missense Mutation (SNP) | VAF 32/126 reads (25%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); called by muse, mutect2, varscan2
- DDX24 | c.917G>T p.S306I | Missense Mutation (SNP) | VAF 14/188 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.091); called by muse, mutect2
- DELE1 | c.1316G>T p.G439V | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- DISP3 | c.1565C>T p.A522V | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DNAH3 | c.3079G>A p.D1027N | Missense Mutation (SNP) | VAF 64/204 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- DNAH7 | c.5350G>T p.G1784C | Missense Mutation (SNP) | VAF 12/165 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.198); called by muse, mutect2
- DST | c.19368T>G p.I6456M (on ENST00000361203 / NM_001374722.1; = p.I4153M on NM_015548.5) | Missense Mutation (SNP) | VAF 23/123 reads (19%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- EDNRB | c.101C>T p.A34V | Missense Mutation (SNP) | VAF 18/360 reads (5%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.429); called by muse, mutect2
- ENOX2 | c.1043G>T p.W348L (on ENST00000338144 / NM_001382520.1; = p.W319L on NM_006375.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/315 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.169); called by muse, mutect2
- EPSTI1 | c.884A>G p.K295R (on ENST00000398762 / NM_001330543.2; = p.K284R on NM_033255.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/288 reads (5%) | SIFT tolerated (0.41); PolyPhen benign (0.006); called by muse, mutect2
- ERBB4 | c.3041A>T p.E1014V | Missense Mutation (SNP) | VAF 27/302 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.039); called by muse, mutect2
- ERBB4 | c.3040G>T p.E1014* | Nonsense Mutation (SNP) | VAF 27/304 reads (9%) | called by muse, mutect2
- ERCC6L | c.2449G>C p.G817R | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- ERCC6L | c.2448G>C p.K816N | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- ETFB | c.325G>A p.A109T | Missense Mutation (SNP) | VAF 61/481 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.78); called by muse, mutect2, varscan2
- EYA1 | c.964G>T p.E322* | Nonsense Mutation (SNP) | VAF 48/466 reads (10%) | called by muse, mutect2, varscan2
- EYA4 | c.1476A>T p.R492S (on ENST00000531901 / NM_001301013.1; = p.R486S on NM_004100.5) | Missense Mutation (SNP) | VAF 11/278 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); called by muse, mutect2
- EYS | c.2810G>T p.C937F | Missense Mutation (SNP) | VAF 20/174 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); called by muse, mutect2, varscan2
- FA2H | c.882G>T p.E294D | Missense Mutation (SNP) | VAF 33/200 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- FAM135B | c.2960C>A p.P987H | Missense Mutation (SNP) | VAF 10/208 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.011); called by muse, mutect2
- FAM166B | c.509T>A p.M170K | Missense Mutation (SNP) | VAF 16/192 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.277); called by muse, mutect2
- FAM50A | c.1011G>T p.T337= | Splice Region (SNP) | VAF 43/163 reads (26%) | called by muse, mutect2, varscan2
- FAM53B | c.650C>T p.P217L | Missense Mutation (SNP) | VAF 19/134 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- FSIP2 | c.19567C>A p.P6523T | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- FUT8 | c.293A>T p.E98V | Missense Mutation (SNP) | VAF 10/181 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.082); called by muse, mutect2
- FUT9 | c.76C>A p.L26I | Missense Mutation (SNP) | VAF 10/129 reads (8%) | SIFT tolerated (0.38); PolyPhen benign (0.009); called by muse, mutect2
- GATA3 | c.868T>A p.Y290N | Missense Mutation (SNP) | VAF 42/606 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GCGR | c.93C>G p.F31L | Missense Mutation (SNP) | VAF 15/145 reads (10%) | SIFT tolerated (0.68); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GIMAP4 | c.400A>T p.T134S | Missense Mutation (SNP) | VAF 18/210 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.029); called by muse, mutect2
- GPR141 | c.527C>G p.T176R | Missense Mutation (SNP) | VAF 23/203 reads (11%) | SIFT tolerated (0.44); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GREB1L | c.2739G>T p.Q913H | Missense Mutation (SNP) | VAF 19/166 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GUSB | c.370G>A p.G124S | Missense Mutation (SNP) | VAF 21/213 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.631); called by muse, mutect2, varscan2
- HAAO | c.683T>A p.V228E | Missense Mutation (SNP) | VAF 11/237 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.882); called by muse, mutect2
- HDAC9 | c.2188C>A p.P730T | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- HEXB | c.133G>T p.A45S | Missense Mutation (SNP) | VAF 38/305 reads (12%) | SIFT tolerated (0.58); PolyPhen benign (0.199); called by muse, mutect2, varscan2
- HNRNPUL2 | c.1781C>T p.A594V | Missense Mutation (SNP) | VAF 16/190 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.558); called by muse, mutect2
- IGHV3-49 | c.113G>T p.R38I | Missense Mutation (SNP) | VAF 34/261 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.417); called by muse, mutect2, varscan2
- IL2RG | c.61G>T p.V21L | Missense Mutation (SNP) | VAF 12/172 reads (7%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.027); called by muse, mutect2
- INSM2 | c.307G>T p.G103W | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.127); called by mutect2, varscan2
- INSM2 | c.1154A>C p.Q385P | Missense Mutation (SNP) | VAF 15/124 reads (12%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- INTS8 | c.439A>T p.N147Y | Missense Mutation (SNP) | VAF 26/209 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- IQSEC2 | c.4406C>A p.T1469K | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.062); called by muse, mutect2
- JMJD7-PLA2G4B | c.2660G>T p.R887L | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.138); called by muse, varscan2
- KANK4 | c.680T>A p.L227Q | Missense Mutation (SNP) | VAF 10/137 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.028); called by muse, mutect2
- KCNF1 | c.269T>C p.I90T | Missense Mutation (SNP) | VAF 20/164 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.023); called by muse, mutect2
- KCNMA1 | c.3334G>T p.D1112Y (on ENST00000286628 / NM_001161352.2; = p.D1054Y on NM_002247.4) | Missense Mutation (SNP) | VAF 35/443 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.492); called by muse, mutect2
- KEL | c.68T>A p.L23H | Missense Mutation (SNP) | VAF 85/569 reads (15%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.257); called by muse, mutect2, varscan2
- KIAA1549 | c.5150G>A p.G1717D | Missense Mutation (SNP) | VAF 13/123 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- KIF26A | c.368G>T p.R123L | Missense Mutation (SNP) | VAF 46/472 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.029); called by muse, mutect2
- KIF3B | c.2089G>T p.E697* | Nonsense Mutation (SNP) | VAF 56/297 reads (19%) | called by muse, mutect2, varscan2
- KNG1 | c.995G>A p.S332N | Missense Mutation (SNP) | VAF 50/446 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- KRT35 | c.274A>T p.I92F | Missense Mutation (SNP) | VAF 27/278 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- LAMA3 | c.7530T>A p.S2510R (on ENST00000313654 / NM_198129.4; = p.S901R on NM_000227.6) | Missense Mutation (SNP) | VAF 32/415 reads (8%) | SIFT tolerated (0.37); PolyPhen benign (0.274); called by muse, mutect2
- LIPC | c.684G>T p.M228I | Missense Mutation (SNP) | VAF 32/418 reads (8%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.493); called by muse, mutect2
- LPO | c.721T>A p.Y241N | Missense Mutation (SNP) | VAF 40/418 reads (10%) | SIFT tolerated (0.34); PolyPhen benign (0.006); called by muse, mutect2
- LRRK2 | c.2156A>T p.Q719L | Missense Mutation (SNP) | VAF 18/409 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.142); called by muse, mutect2
- MAMLD1 | c.446A>G p.Q149R | Missense Mutation (SNP) | VAF 24/633 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.058); called by muse, mutect2
- MAPK8IP3 | c.2596G>T p.G866W | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- MECOM | c.467G>T p.G156V (on ENST00000468789 / NM_001105078.4; = p.G344V on NM_004991.4) | Missense Mutation (SNP) | VAF 12/244 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MED26 | c.1568A>T p.Q523L | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- MSRB1 | c.347A>C p.H116P | Missense Mutation (SNP) | VAF 36/149 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MTMR1 | c.1708G>A p.D570N | Missense Mutation (SNP) | VAF 24/179 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.045); called by muse, varscan2
- MXRA8 | c.23T>A p.L8Q | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- MYCT1 | c.668C>A p.P223H | Missense Mutation (SNP) | VAF 14/144 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MYH1 | c.2420A>T p.K807I | Missense Mutation (SNP) | VAF 18/194 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.695); called by muse, mutect2
- MYO15A | c.5726T>A p.L1909Q | Missense Mutation (SNP) | VAF 29/252 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MYO18B | c.4280A>T p.E1427V | Missense Mutation (SNP) | VAF 14/218 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- NAP1L2 | c.1097C>A p.P366H | Missense Mutation (SNP) | VAF 18/258 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- NHSL2 | c.1806G>T p.Q602H (on ENST00000510661; = p.Q968H on NM_001013627.2) | Missense Mutation (SNP) | VAF 17/153 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.568); called by muse, mutect2, varscan2
- NLRP13 | c.185C>A p.A62D | Missense Mutation (SNP) | VAF 19/334 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- NLRP4 | c.547C>A p.L183M | Missense Mutation (SNP) | VAF 33/224 reads (15%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- NLRP5 | c.3194G>C p.R1065T | Missense Mutation (SNP) | VAF 17/212 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.484); called by muse, mutect2
- NRDC | c.1550A>C p.Q517P | Missense Mutation (SNP) | VAF 12/145 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); called by muse, mutect2
- NUP155 | c.3007G>T p.V1003L (on ENST00000231498 / NM_153485.3; = p.V944L on NM_004298.4) | Missense Mutation (SNP) | VAF 24/304 reads (8%) | SIFT tolerated (0.35); PolyPhen benign (0.09); called by muse, mutect2
- OBSCN | c.14976G>T p.E4992D | Missense Mutation (SNP) | VAF 33/335 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.053); called by muse, mutect2
- OR10T2 | c.528C>A p.N176K | Missense Mutation (SNP) | VAF 12/144 reads (8%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.909); called by muse, mutect2
- OR1J1 | c.679C>A p.Q227K | Missense Mutation (SNP) | VAF 30/233 reads (13%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OR2G3 | c.25C>A p.L9I | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OR4C15 | c.449G>T p.C150F (on ENST00000314644; = p.C96F on NM_001001920.2) | Missense Mutation (SNP) | VAF 30/286 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.929); called by muse, mutect2
- OR51A7 | c.857T>A p.M286K | Missense Mutation (SNP) | VAF 23/328 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.772); called by muse, mutect2
- PACS2 | c.1388G>T p.R463L | Missense Mutation (SNP) | VAF 6/85 reads (7%) | SIFT tolerated (0.39); PolyPhen benign (0.007); called by muse, mutect2
- PASD1 | c.2293G>A p.E765K | Missense Mutation (SNP) | VAF 67/269 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- PCDH10 | c.2867C>A p.P956H | Missense Mutation (SNP) | VAF 16/258 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PCDH12 | c.2819T>A p.V940E | Missense Mutation (SNP) | VAF 23/145 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.806); called by muse, mutect2, varscan2
- PCDH15 | c.4697C>A p.P1566Q | Missense Mutation (SNP) | VAF 30/275 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.616); called by muse, mutect2, varscan2
- PCDH15 | c.2554G>T p.V852L | Missense Mutation (SNP) | VAF 20/310 reads (6%) | SIFT tolerated (0.24); PolyPhen benign (0.268); called by muse, mutect2
- PCDHAC1 | c.2357G>T p.G786V | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- PCDHGA7 | c.176T>A p.L59Q | Missense Mutation (SNP) | VAF 21/178 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PEG3 | c.1678G>C p.D560H | Missense Mutation (SNP) | VAF 11/237 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); called by muse, mutect2
- PES1 | c.150C>G p.H50Q | Missense Mutation (SNP) | VAF 17/236 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.678); called by muse, mutect2
- PGK2 | c.1067T>A p.M356K | Missense Mutation (SNP) | VAF 42/306 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PLCB1 | c.1805C>G p.T602R | Missense Mutation (SNP) | VAF 17/175 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- PLEKHM1 | c.1566C>A p.H522Q | Missense Mutation (SNP) | VAF 18/210 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.095); called by muse, mutect2
- PLXNA4 | c.4147C>A p.R1383S | Missense Mutation (SNP) | VAF 12/164 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); called by muse, mutect2
- PPP4R3B | c.1096C>T p.P366S | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.703); called by muse, mutect2
- PQBP1 | c.278G>A p.R93K | Missense Mutation (SNP) | VAF 16/540 reads (3%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, mutect2
- PQBP1 | c.319C>A p.H107N | Missense Mutation (SNP) | VAF 55/398 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- PRPF4 | c.890C>T p.S297F (on ENST00000374198 / NM_001322267.2; = p.S298F on NM_004697.5) | Missense Mutation (SNP) | VAF 23/388 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PSG3 | c.167A>G p.H56R | Missense Mutation (SNP) | VAF 20/319 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.178); called by muse, mutect2
- PTPRJ | c.2729A>T p.N910I | Missense Mutation (SNP) | VAF 12/384 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2
- PYM1 | c.88C>T p.R30W | Missense Mutation (SNP) | VAF 23/222 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by mutect2, varscan2
- RAB11FIP5 | c.1714C>T p.Q572* | Nonsense Mutation (SNP) | VAF 9/107 reads (8%) | called by muse, mutect2
- RAB15 | c.155T>A p.V52E | Missense Mutation (SNP) | VAF 13/266 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); called by muse, mutect2
- RAB39B | c.236A>T p.Y79F | Missense Mutation (SNP) | VAF 47/380 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RYR2 | c.10035G>T p.R3345S | Missense Mutation (SNP) | VAF 16/248 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.351); called by muse, mutect2
- SCAP | c.911-1G>T p.X304_splice | Splice Site (SNP) | VAF 28/115 reads (24%) | called by muse, mutect2, varscan2
- SCG3 | c.53A>T p.Q18L | Missense Mutation (SNP) | VAF 28/350 reads (8%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0.021); called by muse, mutect2
- SCN2A | c.5157G>C p.L1719F | Missense Mutation (SNP) | VAF 52/561 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SEZ6L | c.2473C>A p.L825M | Missense Mutation (SNP) | VAF 24/246 reads (10%) | SIFT tolerated (0.21); PolyPhen probably damaging (1); called by muse, mutect2
- SFTPB | c.*18A>T | Splice Region (SNP) | VAF 16/159 reads (10%) | called by muse, mutect2, varscan2
- SIGLEC14 | c.1013-2A>T p.X338_splice | Splice Site (SNP) | VAF 7/128 reads (5%) | called by muse, mutect2
- SIN3B | c.1411A>T p.T471S | Missense Mutation (SNP) | VAF 25/192 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.2); called by muse, mutect2, varscan2
- SLC25A43 | c.709C>A p.P237T | Missense Mutation (SNP) | VAF 38/362 reads (10%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.624); called by muse, mutect2
- SLCO6A1 | c.1297G>T p.G433C | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.787); called by muse, mutect2
- SLFN14 | c.2110G>A p.D704N | Missense Mutation (SNP) | VAF 28/286 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- SMR3A | c.160del p.H54Ifs*68 | Frame Shift Del (DEL) | VAF 25/213 reads (12%) | called by mutect2, pindel, varscan2
- SOWAHC | c.316C>G p.P106A | Missense Mutation (SNP) | VAF 6/122 reads (5%) | SIFT tolerated (0.27); PolyPhen benign (0.018); called by muse, mutect2
- SPATA31A7 | c.1043G>T p.G348V | Missense Mutation (SNP) | VAF 56/772 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.853); called by muse, mutect2
- SPATA31D1 | c.719C>G p.P240R | Missense Mutation (SNP) | VAF 52/498 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- SYNGAP1 | c.3716C>A p.A1239D | Missense Mutation (SNP) | VAF 48/568 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.136); called by muse, mutect2
- SYTL5 | c.185G>T p.R62I | Missense Mutation (SNP) | VAF 51/400 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- TAF4 | c.2970G>C p.E990D | Missense Mutation (SNP) | VAF 40/227 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- TAZ | c.218T>A p.M73K | Missense Mutation (SNP) | VAF 32/166 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- TCAF2 | c.2469C>G p.D823E | Missense Mutation (SNP) | VAF 35/309 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- TEF | c.590G>A p.G197D | Missense Mutation (SNP) | VAF 16/322 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.391); called by muse, mutect2
- TENM1 | c.6971T>A p.L2324Q | Missense Mutation (SNP) | VAF 24/181 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- TESK1 | c.1796G>T p.C599F | Missense Mutation (SNP) | VAF 9/127 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.598); called by muse, mutect2
- TFDP3 | c.563G>T p.G188V | Missense Mutation (SNP) | VAF 65/328 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TMEM132C | c.2358C>A p.S786R | Missense Mutation (SNP) | VAF 35/182 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TMPO | c.184C>G p.P62A | Missense Mutation (SNP) | VAF 6/132 reads (5%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); called by muse, mutect2
- TRIP12 | c.4250G>C p.G1417A | Missense Mutation (SNP) | VAF 24/396 reads (6%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.987); called by muse, mutect2
- TRPC5 | c.201C>A p.D67E | Missense Mutation (SNP) | VAF 42/279 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TSGA13 | c.246C>G p.S82R | Missense Mutation (SNP) | VAF 20/294 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.16); called by muse, mutect2
- TSHZ3 | c.1474G>T p.G492C | Missense Mutation (SNP) | VAF 43/594 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2
- TTLL3 | c.959G>T p.G320V | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- UBA1 | c.2633C>T p.A878V | Missense Mutation (SNP) | VAF 66/558 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- UBXN7 | c.694G>T p.D232Y | Missense Mutation (SNP) | VAF 40/346 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- UGT2A1 | c.869T>A p.M290K | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- UPF3B | c.1061G>T p.R354L (on ENST00000276201 / NM_080632.3; = p.R341L on NM_023010.3) | Missense Mutation (SNP) | VAF 30/205 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.347); called by muse, mutect2, varscan2
- USH2A | c.3512C>A p.T1171K | Missense Mutation (SNP) | VAF 67/601 reads (11%) | SIFT tolerated (0.36); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- USPL1 | c.2459G>T p.S820I | Missense Mutation (SNP) | VAF 7/103 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.05); called by muse, mutect2
- UTP25 | c.443G>T p.G148V | Missense Mutation (SNP) | VAF 35/310 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- VCAN | c.4949A>G p.D1650G | Missense Mutation (SNP) | VAF 20/259 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.122); called by muse, mutect2
- VCAN | c.9652+1G>C p.X3218_splice | Splice Site (SNP) | VAF 19/271 reads (7%) | called by muse, mutect2
- WDR75 | c.2176A>G p.N726D | Missense Mutation (SNP) | VAF 18/116 reads (16%) | SIFT tolerated (0.89); PolyPhen benign (0); called by muse, mutect2, varscan2
- WEE1 | c.856A>G p.I286V | Missense Mutation (SNP) | VAF 7/101 reads (7%) | SIFT tolerated (0.26); PolyPhen benign (0.007); called by muse, mutect2
- WNK2 | c.2452C>T p.P818S | Missense Mutation (SNP) | VAF 13/117 reads (11%) | SIFT tolerated (0.83); PolyPhen benign (0); called by muse, mutect2, varscan2
- XPO5 | c.3174+1G>A p.X1058_splice | Splice Site (SNP) | VAF 42/260 reads (16%) | called by muse, mutect2, varscan2
- XYLT1 | c.2828C>A p.P943H | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZBTB12 | c.1320G>C p.K440N | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2
- ZBTB41 | c.2365A>G p.K789E | Missense Mutation (SNP) | VAF 48/515 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.985); called by muse, mutect2
- ZBTB7A | c.913G>T p.D305Y | Missense Mutation (SNP) | VAF 13/159 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); called by muse, mutect2
- ZFP57 | c.1216C>A p.H406N | Missense Mutation (SNP) | VAF 58/747 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ZNF208 | c.1820A>G p.K607R | Missense Mutation (SNP) | VAF 37/349 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- ZNF229 | c.2059G>T p.D687Y | Missense Mutation (SNP) | VAF 46/313 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- ZNF699 | c.994G>T p.D332Y | Missense Mutation (SNP) | VAF 22/210 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- ZNF99 | c.83T>G p.L28* | Nonsense Mutation (SNP) | VAF 34/341 reads (10%) | called by muse, varscan2
- ZP2 | c.1528G>T p.G510W | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- ZXDB | c.1970G>T p.G657V | Missense Mutation (SNP) | VAF 30/363 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ABCA13 | c.13005C>A p.P4335= | Silent (SNP) | VAF 67/406 reads (17%) | called by muse, mutect2, varscan2
- ABCF1 | c.1050C>T p.A350= (on ENST00000326195 / NM_001025091.2; = p.A312= on NM_001090.3) | Silent (SNP) | VAF 34/312 reads (11%) | called by muse, mutect2, varscan2
- AHNAK | c.12183C>A p.P4061= | Silent (SNP) | VAF 48/403 reads (12%) | called by muse, mutect2, varscan2
- ANLN | c.117A>T p.R39= | Silent (SNP) | VAF 18/132 reads (14%) | called by muse, mutect2, varscan2
- ASCC1 | c.1002C>T p.F334= (on ENST00000342444 / NM_001369085.1; = p.F306= on NM_001198798.2 and 8 other RefSeq transcripts) | Silent (SNP) | VAF 54/524 reads (10%) | catalogued as rs1232878292; called by muse, mutect2
- BRCA1 | c.84G>T p.L28= | Silent (SNP) | VAF 32/355 reads (9%) | catalogued as CD086714; called by muse, mutect2
- C8orf58 | c.615C>T p.L205= | Silent (SNP) | VAF 12/94 reads (13%) | called by muse, mutect2, varscan2
- CACNA1E | c.5862C>T p.P1954= | Silent (SNP) | VAF 23/322 reads (7%) | catalogued as rs745747074, COSV62385163; called by muse, mutect2
- CCR5 | c.360C>A p.I120= | Silent (SNP) | VAF 37/227 reads (16%) | catalogued as COSV52753246; called by muse, mutect2, varscan2
- CEP170 | c.4590G>T p.P1530= | Silent (SNP) | VAF 22/279 reads (8%) | called by muse, mutect2, varscan2
- COL19A1 | c.622C>A p.R208= | Silent (SNP) | VAF 18/130 reads (14%) | catalogued as rs186826494, COSV100507491; called by muse, mutect2, varscan2
- CRACD | c.2430G>T p.V810= | Silent (SNP) | VAF 27/229 reads (12%) | called by muse, mutect2, varscan2
- CYP11B1 | c.1392G>T p.L464= | Silent (SNP) | VAF 36/230 reads (16%) | called by mutect2, varscan2
- DDX53 | c.390C>A p.S130= | Silent (SNP) | VAF 25/279 reads (9%) | called by muse, mutect2
- DDX60 | c.3267A>T p.V1089= | Silent (SNP) | VAF 18/259 reads (7%) | called by muse, mutect2
- ECEL1 | c.1437C>T p.Y479= | Silent (SNP) | VAF 10/97 reads (10%) | called by muse, mutect2, varscan2
- EIF2S3B | c.1002C>T p.G334= | Silent (SNP) | VAF 9/135 reads (7%) | catalogued as rs1257950818; called by muse, mutect2
- ETV3 | c.504G>T p.R168= | Silent (SNP) | VAF 27/374 reads (7%) | called by muse, mutect2
- FAM83D | c.1377A>G p.T459= | Silent (SNP) | VAF 45/241 reads (19%) | called by muse, mutect2, varscan2
- FCGR3B | c.15C>A p.L5= | Silent (SNP) | VAF 26/276 reads (9%) | catalogued as COSV54212773; called by muse, mutect2
- FRMPD3 | c.1491C>A p.V497= | Silent (SNP) | VAF 73/370 reads (20%) | called by muse, mutect2, varscan2
- GPR65 | c.693C>A p.I231= | Silent (SNP) | VAF 14/298 reads (5%) | called by muse, mutect2
- GRM1 | c.240G>A p.E80= | Silent (SNP) | VAF 33/346 reads (10%) | catalogued as rs780098207, COSV99264092; called by muse, mutect2
- HMCN2 | c.5649G>A p.K1883= | Silent (SNP) | VAF 24/287 reads (8%) | catalogued as COSV101338644; called by muse, mutect2
- HS6ST2 | c.1185C>T p.S395= | Silent (SNP) | VAF 44/226 reads (19%) | catalogued as rs771609534; called by muse, mutect2, varscan2
- IQSEC2 | c.4404C>A p.G1468= | Silent (SNP) | VAF 4/34 reads (12%) | called by muse, mutect2
- ISLR2 | c.138G>T p.P46= | Silent (SNP) | VAF 16/224 reads (7%) | catalogued as COSV62301856; called by muse, mutect2
- KCNMA1 | c.3333G>T p.A1111= (on ENST00000286628 / NM_001161352.2; = p.A1053= on NM_002247.4) | Silent (SNP) | VAF 35/443 reads (8%) | catalogued as rs200045097, COSV54227798; called by muse, mutect2
- KIF26A | c.369C>T p.R123= | Silent (SNP) | VAF 46/469 reads (10%) | catalogued as rs1019814995; called by muse, mutect2
- KIFC1 | c.1647G>A p.E549= | Silent (SNP) | VAF 26/214 reads (12%) | called by muse, varscan2
- L1CAM | c.3060T>C p.F1020= | Silent (SNP) | VAF 27/153 reads (18%) | called by muse, mutect2, varscan2
- LRRK2 | c.7365C>T p.V2455= | Silent (SNP) | VAF 17/131 reads (13%) | called by muse, mutect2, varscan2
- MDN1 | c.912G>C p.L304= | Silent (SNP) | VAF 18/204 reads (9%) | called by muse, mutect2
- MUC6 | c.1770C>A p.T590= | Silent (SNP) | VAF 8/150 reads (5%) | called by muse, mutect2
- NOL4 | c.171C>T p.V57= | Silent (SNP) | VAF 41/353 reads (12%) | called by muse, mutect2, varscan2
- NOX4 | c.1068C>A p.L356= | Silent (SNP) | VAF 7/69 reads (10%) | called by muse, mutect2, varscan2
- NPC1L1 | c.3594G>C p.L1198= | Silent (SNP) | VAF 49/348 reads (14%) | catalogued as rs757282762; called by muse, mutect2, varscan2
- NRN1 | c.309C>A p.I103= | Silent (SNP) | VAF 68/436 reads (16%) | called by muse, mutect2, varscan2
- NUTM2F | c.1365C>A p.T455= | Silent (SNP) | VAF 16/186 reads (9%) | catalogued as COSV99480128; called by muse, mutect2
- OR12D2 | c.915A>G p.R305= | Silent (SNP) | VAF 17/112 reads (15%) | called by muse, mutect2, varscan2
- OR13C4 | c.417G>A p.V139= | Silent (SNP) | VAF 9/141 reads (6%) | called by muse, mutect2
- OTUD5 | c.279C>A p.P93= | Silent (SNP) | VAF 24/177 reads (14%) | called by muse, mutect2, varscan2
- PCDHB1 | c.183G>T p.A61= | Silent (SNP) | VAF 19/251 reads (8%) | catalogued as COSV60632074; called by muse, mutect2
- PFKFB1 | c.477C>A p.S159= | Silent (SNP) | VAF 14/162 reads (9%) | called by muse, mutect2
- POF1B | c.144G>T p.V48= | Silent (SNP) | VAF 125/744 reads (17%) | catalogued as COSV99426759; called by muse, mutect2, varscan2
- RBM10 | c.2322C>T p.L774= | Silent (SNP) | VAF 10/306 reads (3%) | catalogued as rs976555482; called by muse, mutect2
- RBMX2 | c.867T>C p.Y289= | Silent (SNP) | VAF 73/455 reads (16%) | catalogued as rs1454520613; called by muse, mutect2, varscan2
- RBP3 | c.735C>A p.I245= | Silent (SNP) | VAF 14/224 reads (6%) | called by muse, mutect2
- RIN2 | c.2055G>A p.P685= (on ENST00000255006 / NM_001242581.1; = p.P636= on NM_018993.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 39/273 reads (14%) | catalogued as rs374436404, COSV54787110; ClinVar: likely benign; called by muse, mutect2, varscan2
- RYR1 | c.5640G>A p.E1880= | Silent (SNP) | VAF 48/416 reads (12%) | catalogued as rs146875363; ClinVar: likely benign; called by muse, mutect2, varscan2
- SBSN | c.606G>A p.E202= | Silent (SNP) | VAF 47/450 reads (10%) | called by muse, varscan2
- SDCCAG8 | c.1140A>T p.A380= | Silent (SNP) | VAF 25/312 reads (8%) | called by muse, mutect2
- SEC31A | c.2652C>T p.P884= (on ENST00000355196 / NM_001318120.1; = p.P845= on NM_016211.4) | Silent (SNP) | VAF 17/111 reads (15%) | called by muse, varscan2
- SIRPG | c.258C>A p.P86= | Silent (SNP) | VAF 50/336 reads (15%) | called by muse, mutect2, varscan2
- SLC1A5 | c.1497A>T p.I499= | Silent (SNP) | VAF 22/284 reads (8%) | called by muse, mutect2
- SLC25A43 | c.708C>A p.L236= | Silent (SNP) | VAF 38/363 reads (10%) | called by muse, mutect2
- SLC9B2 | c.1602T>C p.S534= | Silent (SNP) | VAF 7/60 reads (12%) | catalogued as rs920713872; called by muse, mutect2, varscan2
- SLITRK2 | c.444C>A p.A148= | Silent (SNP) | VAF 44/326 reads (13%) | catalogued as COSV100157552; called by muse, mutect2, varscan2
- SPATA31A6 | c.1674C>G p.V558= | Silent (SNP) | VAF 56/762 reads (7%) | called by muse, mutect2
- STARD3NL | c.177C>T p.V59= | Silent (SNP) | VAF 24/307 reads (8%) | called by muse, mutect2
- STK32C | c.528G>T p.G176= | Silent (SNP) | VAF 28/296 reads (9%) | catalogued as COSV53838987; called by muse, mutect2
- STMP1 | c.45A>T p.G15= | Silent (SNP) | VAF 28/263 reads (11%) | called by muse, mutect2, varscan2
- TBCD | c.303G>T p.L101= | Silent (SNP) | VAF 10/196 reads (5%) | called by muse, mutect2
- TNFSF4 | c.111C>T p.L37= | Silent (SNP) | VAF 20/283 reads (7%) | called by muse, mutect2
- TRGV2 | c.84A>T p.S28= | Silent (SNP) | VAF 26/264 reads (10%) | called by muse, mutect2, varscan2
- TUBA3D | c.282C>A p.T94= | Silent (SNP) | VAF 20/344 reads (6%) | called by muse, mutect2
- UBE4A | c.1080C>T p.P360= (on ENST00000252108 / NM_001204077.2; = p.P367= on NM_004788.4) | Silent (SNP) | VAF 21/116 reads (18%) | catalogued as COSV99348192; called by muse, mutect2, varscan2
- USP5 | c.816G>T p.L272= | Silent (SNP) | VAF 11/231 reads (5%) | catalogued as rs1449397193; called by muse, mutect2
- VCPKMT | c.684A>G p.P228= | Silent (SNP) | VAF 17/190 reads (9%) | catalogued as rs1477760175; called by muse, mutect2
- WDR46 | c.918G>T p.V306= | Silent (SNP) | VAF 18/152 reads (12%) | called by muse, mutect2, varscan2
- ZFR2 | c.942G>T p.G314= | Silent (SNP) | VAF 24/246 reads (10%) | called by muse, mutect2
- AC105942.1 | n.1068G>C | RNA (SNP) | VAF 25/294 reads (9%) | called by muse, mutect2
- AGXT2 | c.-51A>G | 5'UTR (SNP) | VAF 18/173 reads (10%) | called by muse, mutect2, varscan2
- AL355390.1 | n.536T>C | RNA (SNP) | VAF 15/203 reads (7%) | called by muse, mutect2
- AOC4P | n.243G>T | RNA (SNP) | VAF 21/143 reads (15%) | called by muse, mutect2, varscan2
- CCNYL2 | n.1366T>A | RNA (SNP) | VAF 28/260 reads (11%) | called by muse, mutect2, varscan2
- CDRT1 | c.872-33G>C | Intron (SNP) | VAF 22/260 reads (8%) | called by muse, mutect2
- COG6 | c.*936C>G | 3'UTR (SNP) | VAF 12/211 reads (6%) | called by muse, mutect2
- CTAGE1 | c.*828G>A | 3'UTR (SNP) | VAF 30/283 reads (11%) | called by muse, mutect2, varscan2
- DCAF17 | c.*2895G>T | 3'UTR (SNP) | VAF 13/99 reads (13%) | catalogued as COSV59830049; called by muse, mutect2, varscan2
- DENND10P1 | n.344A>G | RNA (SNP) | VAF 102/697 reads (15%) | catalogued as rs769358091; called by muse, mutect2, varscan2
- DLD | c.-51G>T | 5'UTR (SNP) | VAF 32/233 reads (14%) | catalogued as COSV99227223; called by muse, mutect2, varscan2
- DST | c.4297-4841A>T | Intron (SNP) | VAF 13/105 reads (12%) | called by muse, mutect2, varscan2
- EDN2 | c.*38G>T | 3'UTR (SNP) | VAF 30/468 reads (6%) | catalogued as COSV101006339; called by muse, mutect2
- EI24P4 | n.815C>A | RNA (SNP) | VAF 31/219 reads (14%) | called by muse, mutect2, varscan2
- GABRG3 | c.1123-1901G>T | Intron (SNP) | VAF 26/242 reads (11%) | called by muse, mutect2, varscan2
- GRIN1 | c.672-43G>T | Intron (SNP) | VAF 11/148 reads (7%) | called by muse, mutect2
- H3C3 | c.*6C>T | 3'UTR (SNP) | VAF 30/194 reads (15%) | called by muse, mutect2, varscan2
- HMOX1 | c.23+23G>C | Intron (SNP) | VAF 10/119 reads (8%) | called by muse, mutect2
- HNRNPA3P1 | n.628G>C | RNA (SNP) | VAF 16/270 reads (6%) | called by muse, mutect2
- HTR3D | chr3:184031760 C>A | 5'Flank (SNP) | VAF 26/205 reads (13%) | called by muse, mutect2, varscan2
- HUWE1 | c.12531+33C>A | Intron (SNP) | VAF 52/424 reads (12%) | catalogued as COSV53358666; called by muse, mutect2, varscan2
- IKBIP | c.297+7674C>T | Intron (SNP) | VAF 21/142 reads (15%) | called by muse, mutect2, varscan2
- IKBIP | c.297+7673C>T | Intron (SNP) | VAF 22/141 reads (16%) | called by muse, mutect2, varscan2
- L1CAM | c.1268-49G>C | Intron (SNP) | VAF 17/94 reads (18%) | called by muse, mutect2
- LAMA5 | c.2165-182G>T | Intron (SNP) | VAF 45/271 reads (17%) | called by muse, mutect2, varscan2
- LCT | c.5111+25G>T | Intron (SNP) | VAF 30/325 reads (9%) | called by muse, mutect2
- LCT | c.5111+24G>T | Intron (SNP) | VAF 28/326 reads (9%) | called by muse, mutect2
- MFSD4B | c.*368G>T | 3'UTR (SNP) | VAF 10/178 reads (6%) | called by muse, mutect2
- MIR4739 | chr17:79707534 C>A | 5'Flank (SNP) | VAF 16/170 reads (9%) | called by muse, mutect2
- MS4A4A | c.41+2023G>C | Intron (SNP) | VAF 7/58 reads (12%) | called by muse, mutect2, varscan2
- NAPA | c.561+159C>T | Intron (SNP) | VAF 7/94 reads (7%) | called by muse, mutect2
- OR7E5P | n.565C>A | RNA (SNP) | VAF 59/580 reads (10%) | catalogued as rs560615671; called by muse, mutect2, varscan2
- PCLO | c.13655-1627C>T | Intron (SNP) | VAF 8/67 reads (12%) | catalogued as rs189583870; called by muse, mutect2, varscan2
- PTRH1 | c.96+61T>C | Intron (SNP) | VAF 10/164 reads (6%) | called by muse, mutect2
- RNA5-8SP2 | n.152G>T | RNA (SNP) | VAF 6/76 reads (8%) | called by muse, mutect2
- RNA5S17 | chr1:228650328 G>T | 5'Flank (SNP) | VAF 37/232 reads (16%) | called by muse, mutect2, varscan2
- SLC12A1 | c.-217G>A | 5'UTR (SNP) | VAF 25/153 reads (16%) | called by muse, mutect2, varscan2
- SNORD116-17 | chr15:25088179 C>A | 3'Flank (SNP) | VAF 16/156 reads (10%) | called by muse, mutect2, varscan2
- SSPOP | n.15361T>C | RNA (SNP) | VAF 50/399 reads (13%) | called by muse, mutect2, varscan2
- SSPOP | n.15362G>T | RNA (SNP) | VAF 49/395 reads (12%) | called by muse, mutect2, varscan2
- SVIL2P | n.2336C>T | RNA (SNP) | VAF 8/148 reads (5%) | called by muse, mutect2
- SYNE1 | c.9807+20G>A | Intron (SNP) | VAF 12/314 reads (4%) | called by muse, mutect2
- TAZ | c.*603A>T | 3'UTR (SNP) | VAF 103/511 reads (20%) | called by muse, mutect2, varscan2
- TIMP1 | c.453+331A>C | Intron (SNP) | VAF 7/30 reads (23%) | called by muse, mutect2, varscan2
- TMCO1 | c.*2695A>T | 3'UTR (SNP) | VAF 56/538 reads (10%) | called by muse, mutect2, varscan2
- TMEM70 | c.*189A>G | 3'UTR (SNP) | VAF 36/271 reads (13%) | called by muse, mutect2, varscan2
- TMPRSS3 | c.*430C>T | 3'UTR (SNP) | VAF 26/208 reads (13%) | called by muse, mutect2, varscan2
- TSPAN13 | c.-55G>A | 5'UTR (SNP) | VAF 11/241 reads (5%) | catalogued as rs878935164; called by muse, mutect2
- VPS51 | c.2089-103del | Intron (DEL) | VAF 12/132 reads (9%) | called by mutect2, pindel
- ZNF99 | c.*244A>T | 3'UTR (SNP) | VAF 25/207 reads (12%) | catalogued as rs374935666; called by muse, mutect2, varscan2
